Gene-level copy-number profile of specimen HCM-BROD-0122-C25-85A from HCMI case HCM-BROD-0122-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 69.1 years (25,255 days).
Specimen HCM-BROD-0122-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 6.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 9be1fa4e-e357-4ce2-bca6-335047971d3e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0122-C25-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,258 have no estimate.
https://portal.gdc.cancer.gov/files/20a33062-e703-4e50-ae83-6653c9f7f000

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 1,274; copy number 2: 4,232; copy number 3: 14,401; copy number 4: 30,063; copy number 5: 5,003; copy number 6: 2,916; copy number 7: 149; copy number 8: 50; copy number 9: 78; copy number 10: 93; copy number 11: 96; copy number 13: 1; copy number 72: 5.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr18:15,247,429–15,330,282, 4 genes: BNIP3P3, AP005901.4, AP005901.1, RNU6-721P.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 273 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:61,865,755–61,911,022, 2 genes, copy number 10–11: AL391987.4, FAM242E.
- chr18:45,034–4,459,458, 100 genes, copy number 11–72 (broad region; genes not listed).
- chr18:6,454,962–6,495,668, 3 genes, copy number 9: RNU6-349P, RPL6P27, AP005202.2.
- chr18:12,785,478–13,216,367, 10 genes, copy number 9: PTPN2, STK25P1, EIF4A2P1, SEH1L, AP002449.1, CEP192, AP001357.2, AP001357.1, AP001198.2, AP001198.1.
- chr18:23,134,564–27,190,698, 74 genes, copy number 9–10 (within-gene range 8–10) (broad region; genes not listed).
- chr18:33,552,123–36,780,055, 49 genes, copy number 10–11 (within-gene range 6–11): AC091198.1, ASXL3, NOL4, Y_RNA, AC104985.3, AC104985.1, AC104985.2, DTNA, AC013290.1, AC022601.1, AC068506.1, MAPRE2, AC015967.2, AC015967.1, ZNF397, ZSCAN30, AC011815.3, AC011815.2, AC011815.1, ZNF271P, AC116447.1, ZNF24, ZNF396, AC007998.1, AC007998.4, AC007998.3, AC007998.2, INO80C, AC007998.5, GALNT1, MIR3975, AC090220.1, AC090229.1, NRBF2P1, MIR187, MIR3929, AC118757.1, AC091060.1, C18orf21, RPRD1A, SLC39A6, ELP2, AC023043.1, MOCOS, AC023043.4, AC023043.2, AC023043.3, FHOD3, AC055840.1.
- chr18:37,234,119–42,691,422, 35 genes, copy number 9–10: AC015961.1, CELF4, AC015961.2, AC090386.1, AC090386.2, AC129908.1, AC009899.1, MIR4318, RPL12P40, AC100781.1, RN7SKP182, RNU6-706P, MIR924HG, AC011139.1, RPL7AP66, MIR924, AC099845.1, MIR5583-2, MIR5583-1, RNU6-1242P, LINC01901, LINC01902, AC011266.1, LINC01477, RPL17P45, AC079052.1, KC6, NPM1P1, AC011225.1, PIK3C3, AC087683.2, AC087683.1, LINC00907, RNA5SP454, AC084335.1.

Autosomal genes at a single copy (total copy number 1): 732. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
